Gene-level copy-number profile of tumor specimen TCGA-24-1614-01A from TCGA case TCGA-24-1614, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.5 years (20,993 days).
Specimen TCGA-24-1614-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.28fdfe2a-9e7e-465f-8d05-a232d01be466.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1614-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1bd5f891-b941-4a76-97cd-b3807a7c1eab

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,030; copy number 2: 19,778; copy number 3: 7,907; copy number 4: 23,918; copy number 5: 2,075; copy number 6: 3,399; copy number 7: 1,163; copy number 8: 246; copy number 9: 92; copy number 11: 199.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1614-01): tumor purity 0.91, ploidy 3.35, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:14,692,129–14,777,727, 2 genes: TBCAP2, AL031293.1.
- chr5:156,458,398–156,458,507, 1 gene: AC027308.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 291 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:123,157,729–127,482,139, 92 genes, copy number 9 (broad region; genes not listed).
- chr19:27,638,483–35,279,821, 199 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,030. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
